TCGA case TCGA-CG-4441 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/37e22429-efd7-4d6a-b79a-9d8c7be2170c

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 83 years; Vital status: Dead; Days to death: 426 days (1.2 years).

Diagnoses (1)
1. Adenocarcinoma, intestinal type: ICD-O-3 morphology code: 8144/3; ICD-10 code: C16.2; Tissue or organ of origin: Body of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 83.6 years (30,528 days); Year of diagnosis: 2006; AJCC staging edition: 5th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Lymph nodes positive: 14; Lymph nodes tested: 16.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 426.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CG-4441-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-CG-4441-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 22; Percent lymphocyte infiltration: 8; Percent neutrophil infiltration: 2.
  Slide TCGA-CG-4441-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 25; Percent lymphocyte infiltration: 15; Percent neutrophil infiltration: 10.
- Sample TCGA-CG-4441-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CG-4441-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Cancer procurement city: Hamburg.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 426 days; disease-specific survival: event status not recorded, 426 days; progression-free interval: no event (censored), 426 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CG-4441-01A-01D-1799-01): tumor purity 0.63, ploidy 2.05, whole-genome doublings 0.
